TCGA case TCGA-28-5208 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46bfebf4-0ef6-4348-81dc-d7d3cb52c08f

Demographics
Sex at birth: male; Race: white; Age at index: 52 years; Vital status: Dead; Days to death: 544 days (1.5 years).

Diagnoses (3)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 52.2 years (19,053 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 11 days; Days to treatment end: 49 days; Number of cycles: 1; Treatment dose: 5,320 mg; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 13 days; Days to treatment end: 54 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 13 days; Days to treatment end: 54 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 149 days; Days to treatment end: 285 days; Number of cycles: 5; Treatment dose: 9,750 mg; Prescribed dose: 390; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Recurrent Disease; Days to treatment start: 159 days; Days to treatment end: 159 days; Treatment dose: 1,800 cGy; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Recurrent Disease; Days to treatment start: 159 days; Days to treatment end: 159 days; Treatment dose: 1,800 cGy; Course number: 2; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 287 days; Days to treatment end: 435 days (1.2 years); Number of cycles: 5; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Irinotecan Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 287 days; Days to treatment end: 435 days (1.2 years); Number of cycles: 5; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 52.6 years (19,201 days); Days to diagnosis: 148 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 52.6 years (19,201 days); Days to diagnosis: 148 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (5 entries)
- Day 148 (post initial treatment): Progression or recurrence: Yes; Days to progression: 148 days.
- Days to follow up: 474 days (1.3 years); Disease response: With Tumor.
- Karnofsky performance status: 70; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Timepoint: Post Initial Treatment.
- Follow-up contact recording only the day: day 544.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-28-5208-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-28-5208-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-28-5208-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
- Sample TCGA-28-5208-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Regimen number: 01; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 03; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Recurrence.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 5: Regimen number: 02; Pharmaceutical therapy drug name: Temodar; Therapy regimen: Recurrence.
- Drug treatment 6: Pharmaceutical therapy drug name: CPT11; Therapy regimen: Recurrence.
- Drug treatment 8: Regimen number: 03; Pharmaceutical therapy drug name: CPT11; Therapy regimen: Recurrence.
- Radiation treatment 3: Radiation type other: Gamma Knife; Therapy regimen: Recurrence.
- Follow-up form 3: Lost to follow-up: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 544 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 544 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 148 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-28-5208-01A-01D-1479-01): tumor purity 0.87, ploidy 2, whole-genome doublings 0.
